Somatic mutation profile of tumor specimen TARGET-10-PARGJH-09A (aliquot TARGET-10-PARGJH-09A-01D) from TARGET case TARGET-10-PARGJH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (552 days).
Specimen TARGET-10-PARGJH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf8858b4-bc60-4cff-8396-d637f3f86155.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGJH-10A (Blood Derived Normal), aliquot TARGET-10-PARGJH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b57c268f-5495-4246-b87e-3512cdcdf3bd

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, 3'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 62/159 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSF3R | c.137G>T p.C46F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370699677; called by muse, mutect2, varscan2
- GLI2 | c.2062G>A p.D688N (on ENST00000361492 / NM_001374353.1; = p.D705N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs751513015, COSV58038479; ClinVar: uncertain significance; called by mutect2, varscan2
- OR2F1 | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs1259282652; called by muse, mutect2
- SMC6 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1400628633; called by muse, mutect2
- APOBR | c.1229C>A p.A410D (on ENST00000431282; = p.A419D on NM_018690.4) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BTG1 | c.300_307delinsGC p.S100_T103delinsRP | In Frame Del (DEL) | VAF 13/75 reads (17%) | called by pindel, varscan2*
- CASP10 | c.1281G>T p.Q427H (on ENST00000272879 / NM_032974.5; = p.Q384H on NM_001230.5) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- COL6A1 | c.2452T>G p.Y818D | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CPSF1 | c.1393-4G>T | Splice Region (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- PRPF4B | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SEC13 | c.712G>T p.G238C (on ENST00000350697 / NM_183352.3; = p.G241C on NM_030673.4) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2
- SPIN1 | c.329C>A p.A110E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TRANK1 | c.7853G>T p.G2618V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF254 | c.1665T>A p.F555L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF384 | c.1049G>T p.C350F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- DHRS7B | c.57C>A p.I19= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- ESPL1 | c.1608C>A p.P536= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- SLC1A1 | c.1333C>A p.R445= | Silent (SNP) | VAF 43/54 reads (80%) | catalogued as CM110109, COSV52049806; called by muse, mutect2, varscan2
- SULF1 | c.*738A>G | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
